Somatic mutation profile of tumor specimen MMRF_1772_1_PB_CD138pos (aliquot MMRF_1772_1_PB_CD138pos_T2_KBS5U_L06505) from MMRF case MMRF_1772, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.8 years (17,827 days).
Specimen MMRF_1772_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 165d9c9a-06fd-4ff6-9da8-741e64f42653.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1772_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1772_1_PB_CD3pos_C4_KBS5U_L06507; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce506356-d79e-45c1-a674-39f86a3a6905

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMZ1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
